Somatic mutation profile of tumor specimen TARGET-40-NAAEDI-06A (aliquot TARGET-40-NAAEDI-06A-01D) from TARGET case TARGET-40-NAAEDI, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of upper limb, scapula and associated joints; Age at diagnosis: 15.5 years (5,663 days).
Specimen TARGET-40-NAAEDI-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf6f2ace-7f0b-4242-8b46-9fa865d62302.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAEDI-10A (Blood Derived Normal), aliquot TARGET-40-NAAEDI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/149c1c32-9954-4ebd-872a-fa7b604d665d

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Splice Region 1, Intron 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLG | c.1403C>A p.S468Y | Missense Mutation (SNP) | VAF 54/222 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV64246264; called by mutect2, varscan2
- PGM1 | c.1602C>A p.V534= | Splice Region (SNP) | VAF 15/130 reads (12%) | catalogued as rs772493314; called by muse, mutect2, varscan2
- RBM12 | c.1772A>T p.Q591L | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as COSV58290580; called by muse, mutect2
- CCDC66 | c.2467G>C p.E823Q (on ENST00000394672 / NM_001353147.1; = p.E789Q on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- DNAH9 | c.8401G>A p.E2801K | Missense Mutation (SNP) | VAF 206/887 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- IFTAP | c.659G>T p.C220F | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.108); called by muse, mutect2
- MUC16 | c.41533_41543+17del p.X13845_splice | Splice Site (DEL) | VAF 10/98 reads (10%) | called by mutect2, pindel
- NELL1 | c.1561G>T p.E521* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
- PCLO | c.4032C>G p.D1344E | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- DNAH9 | c.6924G>A p.Q2308= | Silent (SNP) | VAF 143/691 reads (21%) | called by muse, mutect2, varscan2
- IRAG1 | c.2169A>G p.P723= | Silent (SNP) | VAF 11/61 reads (18%) | called by muse, mutect2, varscan2
- PGM1 | c.1524G>A p.G508= | Silent (SNP) | VAF 8/61 reads (13%) | called by muse, mutect2, varscan2
- ACMSD | c.580+9C>T | Intron (SNP) | VAF 12/82 reads (15%) | catalogued as rs777196076, COSV51607932, COSV51608736; called by muse, mutect2, varscan2
